Somatic mutation profile of tumor specimen TCGA-Q1-A73P-01A (aliquot TCGA-Q1-A73P-01A-11D-A32I-09) from TCGA case TCGA-Q1-A73P, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1; Age at diagnosis: 45.0 years (16,450 days).
Specimen TCGA-Q1-A73P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 245ba771-8ea0-419d-88a3-1f19eff5d279.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A73P-10B (Blood Derived Normal), aliquot TCGA-Q1-A73P-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5b1a239-c232-4fe5-9e20-efcf967d62b3

The open-access MAF lists 266 somatic variants for this specimen: 198 protein-altering or splice-affecting, 61 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 61, Nonsense Mutation 22, Splice Site 4, Frame Shift Del 3, Intron 3, RNA 2, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51905987; called by muse, mutect2, varscan2
- ADD1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV53267988; called by muse, mutect2, varscan2
- AKNA | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV56312624; called by muse, mutect2, varscan2
- AMBRA1 | c.1252G>C p.E418Q (on ENST00000458649 / NM_001367468.1; = p.E328Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs778644871, COSV100095652, COSV54053988; called by muse, mutect2, varscan2
- ANKLE2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV61709456; called by muse, mutect2, varscan2
- AP5B1 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV57502958; called by muse, mutect2, varscan2
- APBA2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV67104752; called by muse, mutect2, varscan2
- APBB2 | c.2151G>T p.Q717H (on ENST00000295974 / NM_001166050.2; = p.Q718H on NM_004307.2) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99922243; called by muse, mutect2, varscan2
- ARGFX | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV57681597, COSV57682310; called by muse, mutect2, varscan2
- ARHGAP21 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64543653; called by muse, mutect2, varscan2
- ARHGAP28 | c.1066G>C p.D356H (on ENST00000383472 / NM_001366230.1; = p.D197H on NM_001010000.3) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51637454; called by muse, mutect2, varscan2
- ARHGAP35 | c.4315C>T p.R1439W | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs986522562, COSV68331276; called by muse, mutect2, varscan2
- ARHGAP36 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs267606352, COSV52266787, COSV99357664; called by muse, mutect2, varscan2
- ARHGAP5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV61535555; called by muse, mutect2, varscan2
- ARHGEF11 | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV63812504; called by muse, mutect2, varscan2
- ARMC4 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53464978; called by muse, mutect2, varscan2
- ATAD3B | c.*126-1G>A | Splice Site (SNP) | VAF 39/102 reads (38%) | catalogued as COSV58020755; called by muse, mutect2, varscan2
- ATP11C | c.3329C>A p.S1110* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV59563958; called by muse, mutect2, varscan2
- ATRAID | c.637A>G p.N213D (on ENST00000611786; = p.N100D on NM_016085.5) | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV53026883; called by muse, mutect2, varscan2
- ATXN1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55216644; called by muse, mutect2, varscan2
- BCLAF1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV62142148; called by muse, mutect2, varscan2
- BICRAL | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58405607, COSV58408759; called by muse, mutect2, varscan2
- C1GALT1C1 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV58974189; called by muse, mutect2, varscan2
- C5 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV56327264; called by muse, mutect2, varscan2
- C8B | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.519); catalogued as COSV64777638; called by muse, mutect2, varscan2
- CABIN1 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV99572482; called by muse, mutect2
- CACNA1I | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60808265; called by muse, mutect2, varscan2
- CC2D2A | c.3322C>T p.Q1108* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV101052622; called by muse, varscan2
- CCDC126 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56740079; called by muse, mutect2, varscan2
- CCNJL | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV57444790; called by muse, mutect2, varscan2
- CD40LG | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as CM104217, COSV65698483, COSV65698651; called by muse, mutect2, varscan2
- CD55 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58576972; called by muse, mutect2, varscan2
- CDCA5 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51869548; called by muse, varscan2
- CDHR5 | c.2452G>C p.E818Q (on ENST00000358353 / NM_001171968.2; = p.E824Q on NM_021924.5) | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV57642332, COSV57642954; called by muse, mutect2, varscan2
- CELF6 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV54716445, COSV54717144; called by muse, mutect2, varscan2
- CEP170 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60509095; called by muse, mutect2, varscan2
- CFAP61 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV55629435; called by muse, mutect2, varscan2
- CFAP77 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as rs771075808, COSV58011022; called by muse, mutect2, varscan2
- CGN | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs753953511, COSV54969952; called by muse, mutect2, varscan2
- CIT | c.3535G>A p.E1179K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV55869049; called by muse, mutect2, varscan2
- CIZ1 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV52971459; called by muse, mutect2, varscan2
- CLNK | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553669861, COSV57012508, COSV57015657; called by muse, mutect2, varscan2
- CLNK | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.747); catalogued as rs776858418, COSV57015022; called by muse, mutect2, varscan2
- CLPB | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV53629834; called by muse, mutect2, varscan2
- CNNM4 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV65660858; called by muse, mutect2, varscan2
- COG5 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1194450380, COSV51751018; called by muse, mutect2, varscan2
- COX7A2L | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as rs1339111652, COSV99309865; called by muse, mutect2, varscan2
- CSDE1 | c.559C>T p.Q187* (on ENST00000358528 / NM_001007553.3; = p.Q156* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV54746644, COSV54759666; called by muse, mutect2, varscan2
- DCHS1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs747608620, COSV55035631; called by muse, mutect2, varscan2
- DCX | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57569498; called by muse, mutect2, varscan2
- DDX3X | c.1520C>T p.S507L (on ENST00000399959; = p.S508L on NM_001356.5) | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV67863590, COSV67864564; called by muse, mutect2, varscan2
- DDX60 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV67096740; called by muse, mutect2, varscan2
- DHH | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57201989; called by muse, mutect2, varscan2
- DHX38 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV51697928; called by muse, mutect2, varscan2
- DNAJC1 | c.1466G>C p.R489T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV65411064; called by muse, mutect2, varscan2
- DNAJC1 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV65411070; called by muse, mutect2, varscan2
- DSEL | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV59491535, COSV59493213; called by muse, mutect2, varscan2
- DTWD1 | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52071736; called by muse, mutect2, varscan2
- DUSP7 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV56589052; called by muse, mutect2, varscan2
- ECI2 | c.1035G>T p.L345F (on ENST00000380118 / NM_206836.3; = p.L315F on NM_006117.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV60986470, COSV60987812; called by muse, mutect2, varscan2
- EFCAB6 | c.1136G>C p.R379T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV53057284, COSV53063285; called by muse, mutect2
- EPYC | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV53799756; called by muse, mutect2, varscan2
- FAM114A2 | c.1305C>G p.F435L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV61077876; called by muse, mutect2, varscan2
- FAM135B | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV52724942; called by muse, mutect2, varscan2
- FAM47C | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as COSV63726629; called by muse, mutect2, varscan2
- FBXO24 | c.566C>T p.S189L (on ENST00000241071 / NM_033506.3; = p.S227L on NM_012172.5) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); catalogued as rs1432781682, COSV53826004; called by muse, mutect2, varscan2
- FKBP2 | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100501710; called by muse, mutect2
- FKBP4 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV50009089; called by muse, mutect2, varscan2
- FNDC1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51931917; called by muse, mutect2, varscan2
- FUBP1 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV99627489; called by muse, mutect2, varscan2
- GABRB3 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.966); catalogued as COSV54664336; called by muse, mutect2, varscan2
- GPRASP1 | c.2746G>C p.E916Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as COSV64355588, COSV64356113; called by muse, mutect2, varscan2
- GRIA3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52059840; called by muse, mutect2, varscan2
- GRM3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV64467252; called by muse, mutect2, varscan2
- HAS2 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58262513, COSV58264074; called by muse, mutect2, varscan2
- HELZ2 | c.4111C>T p.H1371Y (on ENST00000467148 / NM_001037335.2; = p.H802Y on NM_033405.3) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71295934; called by muse, mutect2, varscan2
- HIF1A | c.1690C>G p.P564A | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60189268; called by muse, mutect2, varscan2
- HIP1 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61185884; called by muse, mutect2, varscan2
- HIVEP3 | c.1440G>C p.E480D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV56015528; called by muse, mutect2, varscan2
- HLA-A | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs199474481, COSV65138007; called by muse, mutect2, varscan2
- HMGA1 | c.165G>C p.K55N (on ENST00000311487 / NM_001319082.2; = p.K44N on NM_002131.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58988454; called by muse, mutect2, varscan2
- HOXC10 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57726241; called by muse, mutect2, varscan2
- HS3ST3A1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52375516; called by muse, mutect2, varscan2
- HS3ST5 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV57140576; called by muse, mutect2, varscan2
- IGSF1 | c.1785G>A p.W595* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV63837495; called by muse, mutect2, varscan2
- IQGAP1 | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as COSV51585645; called by muse, mutect2, varscan2
- IRAK1BP1 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1397992263, COSV64047830; called by muse, mutect2, varscan2
- JAKMIP2 | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs758985625, COSV54604584; called by muse, mutect2, varscan2
- JAKMIP3 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1383293210, COSV100058512; called by muse, mutect2
- JMJD7-PLA2G4B | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59824207; called by mutect2, varscan2
- KIF13A | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV52451179; called by muse, mutect2, varscan2
- KRTAP13-1 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100819844, COSV62663368; called by muse, mutect2, varscan2
- KTN1 | c.524-1G>A p.X175_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV68023529; called by muse, mutect2, varscan2
- LGALS7B | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs771820960, COSV59251947; called by muse, mutect2, varscan2
- LMO7 | c.645A>C p.E215D (on ENST00000357063; = p.E230D on NM_005358.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV58536468; called by muse, varscan2
- LMO7 | c.710C>G p.S237C (on ENST00000357063; = p.S252C on NM_005358.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407300130, COSV58536482; called by muse, varscan2
- LRRC37A2 | c.4079C>T p.S1360L | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV60236228; called by muse, varscan2
- MAGEL2 | c.3746G>A p.R1249H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.005); catalogued as rs745776063, COSV100045925, COSV58566257; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP1A | c.7582G>A p.E2528K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV55808795; called by muse, mutect2, varscan2
- MAP3K14 | c.1223G>C p.R408T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.248); catalogued as COSV60923596, COSV60924045; called by muse, mutect2, varscan2
- MAP9 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV60904707; called by muse, mutect2, varscan2
- MAPT | c.775G>A p.A259T (on ENST00000262410 / NM_001377265.1; = p.A184T on NM_016835.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs377597373, COSV52240437; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCC | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs369310896; called by muse, mutect2, varscan2
- MCTP2 | c.2271G>C p.L757F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.199); catalogued as COSV63293555; called by muse, mutect2, varscan2
- MDN1 | c.10554G>T p.Q3518H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.818); catalogued as COSV65521611; called by muse, mutect2, varscan2
- MED13 | c.5272C>T p.R1758* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV67263544; called by muse, mutect2, varscan2
- MGA | c.2422G>C p.E808Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54952941, COSV54953823; called by muse, mutect2, varscan2
- MICAL3 | c.4301C>T p.S1434F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.605); catalogued as rs747075038, COSV71588316; called by muse, mutect2, varscan2
- MLKL | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs750054698, COSV58205119; called by muse, mutect2, varscan2
- MORN3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs746963598, COSV62507335; called by muse, mutect2, varscan2
- MRS2 | c.1242G>C p.K414N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV51234384; called by muse, mutect2, varscan2
- MYBPC3 | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs377106864, COSV57027573; ClinVar: uncertain significance; called by muse, mutect2
- MYOC | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV50674850; called by muse, mutect2, varscan2
- NAA15 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs367731445; called by muse, mutect2, varscan2
- NCR3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV53001163; called by muse, mutect2, varscan2
- NDUFB11 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52102010, COSV52102189; called by muse, mutect2, varscan2
- NEK9 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53131012; called by muse, mutect2, varscan2
- NFATC2 | c.1994G>A p.R665K | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV65360978; called by muse, mutect2, varscan2
- NPAS3 | c.2164G>A p.D722N (on ENST00000356141 / NM_001164749.2; = p.D690N on NM_022123.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60834783; called by muse, mutect2, varscan2
- OTOGL | c.1813C>A p.Q605K (on ENST00000547103; = p.Q596K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV72006618; called by muse, mutect2, varscan2
- PCDHA12 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs370292278, COSV56489279; called by muse, mutect2, varscan2
- PCNX2 | c.4037C>T p.S1346L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868650073; called by muse, mutect2
- PCOLCE | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV53826014; called by muse, mutect2, varscan2
- PDE8B | c.722A>C p.N241T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.838); catalogued as COSV53737712; called by muse, mutect2
- PIDD1 | c.2275-1G>A p.X759_splice | Splice Site (SNP) | VAF 61/207 reads (29%) | catalogued as COSV57193294; called by muse, mutect2, varscan2
- PIWIL2 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV63249762; called by muse, mutect2, varscan2
- PLPPR4 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64564197, COSV64567996; called by muse, mutect2, varscan2
- POLQ | c.6643C>T p.Q2215* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as rs1269847932, COSV51751941; called by muse, mutect2, varscan2
- PPP4R3A | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV61504672; called by muse, mutect2, varscan2
- PROSER1 | c.2255C>G p.S752C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV61487225; called by muse, mutect2, varscan2
- PSD | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs781541609, COSV50045908; called by muse, mutect2, varscan2
- PSPC1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV58888152; called by muse, varscan2
- PSPC1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV58888158; called by muse, varscan2
- PTBP1 | c.1042-1G>C p.X348_splice (on ENST00000349038 / NM_031991.4; = p.X374_splice on NM_002819.5) | Splice Site (SNP) | VAF 33/81 reads (41%) | catalogued as COSV62459949; called by muse, mutect2, varscan2
- PTPN22 | c.1065C>A p.D355E (on ENST00000359785 / NM_001193431.2; = p.D300E on NM_012411.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV63085103; called by muse, mutect2, varscan2
- RAB31 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs1484084436, COSV71261539; called by muse, mutect2, varscan2
- RASA3 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774394672, COSV61867373, COSV61868168; called by muse, mutect2, varscan2
- RASIP1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV55804865; called by muse, mutect2, varscan2
- RGS5 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100008902, COSV58352409; called by muse, mutect2, varscan2
- SBDS | c.98A>T p.K33I | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as CM0911446, COSV55887547; called by muse, mutect2, varscan2
- SBNO1 | c.3150G>A p.M1050I (on ENST00000420886; = p.M1049I on NM_018183.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV57338807, COSV57341690; called by muse, mutect2, varscan2
- SBNO1 | c.2914G>A p.D972N (on ENST00000420886; = p.D971N on NM_018183.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57341697, COSV57341845; called by muse, mutect2, varscan2
- SBNO1 | c.2533C>T p.Q845* (on ENST00000420886; = p.Q844* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV57338480, COSV57341708; called by muse, mutect2, varscan2
- SFPQ | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61758679; called by muse, mutect2, varscan2
- SLC1A3 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.474); catalogued as COSV99466844; called by muse, mutect2, varscan2
- SLFN11 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.147); catalogued as COSV57698832; called by muse, mutect2, varscan2
- SPATA31D1 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV61195749; called by muse, mutect2, varscan2
- SPTBN4 | c.3091C>G p.L1031V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV58949396; called by muse, mutect2, varscan2
- TAB3 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV55836963; called by muse, mutect2, varscan2
- TANC2 | c.3103G>C p.E1035Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67334443; called by muse, mutect2, varscan2
- TANGO6 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55765578; called by muse, mutect2, varscan2
- TBX3 | c.2084G>A p.R695H (on ENST00000257566 / NM_016569.4; = p.R675H on NM_005996.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs772126133, COSV57471559; called by muse, mutect2, varscan2
- TCEAL8 | c.353G>C p.*118Sext*20 | Nonstop Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100749794; called by muse, mutect2, varscan2
- TCOF1 | c.4148C>T p.S1383F (on ENST00000377797 / NM_001135243.1; = p.S1306F on NM_000356.4) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs756109392, COSV60348405; called by muse, mutect2, varscan2
- TCTEX1D4 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59499848; called by muse, mutect2, varscan2
- TMC3 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); catalogued as COSV63923168; called by muse, mutect2, varscan2
- TMCO4 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV53872671; called by muse, varscan2
- TMEM237 | c.578C>T p.S193L (on ENST00000409883 / NM_001044385.3; = p.S185L on NM_152388.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV53804808; called by muse, mutect2, varscan2
- TNNT2 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52662621; called by muse, mutect2, varscan2
- TP53BP1 | c.3376G>C p.E1126Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as COSV55501260; called by muse, mutect2, varscan2
- TRIM45 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV56713608; called by muse, mutect2, varscan2
- TRMT61B | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV60258051; called by muse, mutect2, varscan2
- TTC17 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV50008573; called by muse, mutect2, varscan2
- TTLL5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760667390, COSV54033783; called by muse, mutect2, varscan2
- TWNK | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV52968180; called by muse, mutect2, varscan2
- TXLNG | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV66329828; called by muse, mutect2, varscan2
- UGT2B7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59443396; called by muse, mutect2, varscan2
- USP5 | c.2458G>A p.V820I (on ENST00000229268 / NM_001098536.2; = p.V797I on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs782621306, COSV57540253; called by muse, mutect2
- UTP20 | c.7375G>A p.E2459K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV55377085; called by muse, mutect2, varscan2
- VEGFB | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs766505148, COSV100374538; called by muse, mutect2, varscan2
- XKR4 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.007); catalogued as COSV59315365; called by muse, mutect2, varscan2
- YWHAZ | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV62054067; called by muse, mutect2, varscan2
- ZCCHC2 | c.3381G>T p.K1127N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99502068; called by muse, mutect2, varscan2
- ZNF182 | c.975A>T p.K325N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556898321, COSV59357292; called by muse, mutect2, varscan2
- ZNF182 | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as COSV100527260, COSV59356502; called by muse, mutect2
- ZNF326 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV61035256; called by muse, mutect2, varscan2
- ZNF45 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV54193121; called by muse, mutect2, varscan2
- ZNF543 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100386703, COSV58627470; called by muse, mutect2, varscan2
- ZNF626 | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV52480581, COSV52481156; called by muse, mutect2, varscan2
- ZNF677 | c.1742C>G p.S581* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as COSV61720258; called by muse, mutect2, varscan2
- ZNF711 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52153148; called by muse, mutect2, varscan2
- ZNF790 | c.1071G>C p.Q357H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV63212467; called by muse, mutect2, varscan2
- ZNF791 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV58480971; called by muse, mutect2, varscan2
- ZNF804B | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60828096, COSV60840394; called by muse, mutect2
- ZNF85 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV56021703; called by muse, mutect2, varscan2
- ZWILCH | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57179946; called by muse, mutect2, varscan2
- CHRNA9 | c.518_519del p.F173Wfs*23 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- CTSB | c.274_275del p.Q92Vfs*27 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by pindel, varscan2
- CUBN | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCN1 | c.2108_2110del p.T703del | In Frame Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- GORASP1 | c.202_205dup p.L69Qfs*43 | Frame Shift Ins (INS) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- GPR179 | c.1547G>T p.R516L (on ENST00000621958; = p.R515L on NM_001004334.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- LRRK2 | c.7549_7579del p.L2517Sfs*11 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- MACROD2 | c.747_749dup p.E250dup | In Frame Ins (INS) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- XKR3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- XKR3 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | called by muse, varscan2
- ABCA2 | c.6969G>T p.V2323= (on ENST00000614293; = p.V2293= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV55801209, COSV99688298; called by muse, mutect2, varscan2
- ABCA3 | c.3996C>T p.L1332= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV57053638; called by muse, mutect2, varscan2
- ABCA7 | c.2409G>A p.L803= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV54029463; called by muse, mutect2, varscan2
- ACIN1 | c.120G>C p.R40= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV52976303; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2736G>A p.E912= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1447894603, COSV65892263; called by muse, mutect2, varscan2
- AL121899.2 | c.1779G>A p.A593= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs201706734; called by muse, mutect2, varscan2
- ANKS1B | c.3630C>T p.S1210= (on ENST00000547776 / NM_152788.4; = p.S376= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV100226858; called by muse, mutect2, varscan2
- BDKRB1 | c.315C>T p.F105= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs370873606, COSV53706347; called by muse, mutect2, varscan2
- BIRC6 | c.12819G>T p.V4273= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs368206423; called by muse, mutect2, varscan2
- CCDC183 | c.465C>T p.I155= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV62012618; called by muse, mutect2, varscan2
- COL15A1 | c.207C>T p.F69= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs770970455, COSV66641621; called by muse, mutect2, varscan2
- CRIM1 | c.2976G>A p.K992= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1268532055, COSV54864165; called by muse, mutect2, varscan2
- DOK1 | c.795C>G p.L265= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV51207591; called by muse, mutect2, varscan2
- FAM126B | c.1333C>T p.L445= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53772635; called by muse, mutect2, varscan2
- FAM234B | c.318C>G p.V106= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52194587; called by muse, mutect2, varscan2
- FIZ1 | c.378C>G p.L126= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55607820; called by muse, mutect2, varscan2
- FOXI1 | c.276G>A p.Q92= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV60388603; called by muse, mutect2
- GCOM1 | c.534C>T p.L178= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs779044670, COSV51090424; called by muse, mutect2, varscan2
- GEMIN5 | c.3624G>A p.L1208= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV53560622, COSV53562998; called by muse, mutect2, varscan2
- GEMIN5 | c.90C>T p.F30= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs1402915659, COSV53560631; called by muse, mutect2, varscan2
- GGT1 | c.1602C>T p.T534= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV50640397; called by muse, mutect2, varscan2
- GP1BA | c.714C>T p.D238= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV56699485; called by muse, mutect2, varscan2
- GPR179 | c.549G>A p.V183= | Silent (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- GPR31 | c.900C>G p.L300= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV64761442; called by muse, mutect2, varscan2
- HSD17B1 | c.726C>T p.L242= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1220938543, COSV56797766; called by muse, mutect2, varscan2
- INTS5 | c.2553C>T p.F851= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV57951537; called by muse, mutect2, varscan2
- IQCG | c.1092G>A p.K364= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV54562228; called by muse, mutect2, varscan2
- ITGB7 | c.954C>G p.L318= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV57238705; called by muse, mutect2, varscan2
- ITIH1 | c.2517T>G p.G839= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV56254985; called by muse, mutect2, varscan2
- KRT74 | c.378C>T p.N126= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs151100866; called by muse, mutect2, varscan2
- LARP4B | c.987G>T p.V329= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV60221480; called by muse, mutect2, varscan2
- LRRN4 | c.1503G>A p.Q501= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV66645311; called by muse, mutect2, varscan2
- MYO7B | c.1374C>T p.N458= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs374298824; called by muse, mutect2, varscan2
- NSUN4 | c.54C>T p.L18= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as COSV61063122; called by muse, mutect2
- OR4S1 | c.124C>T p.L42= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV60679118, COSV60679338; called by muse, mutect2, varscan2
- PKMYT1 | c.145C>A p.R49= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV51891501; called by muse, mutect2, varscan2
- POLR1A | c.4071G>A p.K1357= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99806958, COSV99807976; called by muse, mutect2
- PRAMEF10 | c.54G>A p.L18= | Silent (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- PTPRT | c.3423G>A p.L1141= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs754327135, COSV61981427; called by muse, mutect2, varscan2
- RELN | c.7641G>A p.A2547= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs749089939, COSV58983944; ClinVar: likely benign; called by muse, mutect2, varscan2
- REXO1 | c.3603C>T p.D1201= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs372526700; called by muse, mutect2, varscan2
- RNGTT | c.1023C>T p.L341= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs372437134, COSV55650909; called by muse, mutect2, varscan2
- SBF2 | c.721C>T p.L241= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV56299216; called by muse, mutect2, varscan2
- SLCO4A1 | c.843G>C p.L281= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as COSV53890896, COSV99415269; called by muse, mutect2, varscan2
- SNX19 | c.2799G>A p.L933= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56285646; called by muse, mutect2, varscan2
- SPATC1 | c.585G>A p.L195= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV66298551, COSV66298898; called by muse, mutect2, varscan2
- SRBD1 | c.1255C>T p.L419= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55398820; called by muse, mutect2, varscan2
- ST7 | c.1185G>A p.L395= (on ENST00000265437 / NM_021908.3; = p.L372= on NM_018412.4) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV55384964; called by muse, mutect2
- SYNE1 | c.12834G>A p.L4278= (on ENST00000367255 / NM_182961.4; = p.L4207= on NM_033071.3) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV54981634; called by muse, mutect2, varscan2
- TATDN2 | c.1503C>T p.H501= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs748553103, COSV55051838; called by muse, mutect2, varscan2
- THAP1 | c.387C>G p.L129= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV54273135; called by muse, mutect2, varscan2
- TNKS | c.3957C>T p.T1319= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs750083974, COSV60057634; called by muse, mutect2, varscan2
- TNR | c.1470G>A p.Q490= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV54885745; called by muse, mutect2, varscan2
- TP73 | c.1113G>T p.L371= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV60701401; called by muse, varscan2
- TRIM36 | c.1636C>T p.L546= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV56690238; called by muse, mutect2, varscan2
- TSSC4 | c.987C>G p.V329= | Silent (SNP) | VAF 76/190 reads (40%) | catalogued as COSV50152829; called by muse, mutect2, varscan2
- UBE3A | c.852G>A p.L284= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99216588; called by muse, mutect2
- UBR1 | c.4204C>T p.L1402= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV51929764; called by muse, mutect2, varscan2
- USP3 | c.1296G>A p.L432= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV51427526; called by muse, mutect2, varscan2
- USPL1 | c.780G>A p.S260= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs778232932, COSV54998756, COSV54999434; called by muse, mutect2, varscan2
- XXYLT1 | c.510C>T p.I170= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59983910; called by mutect2, varscan2
- AL590867.2 | n.90C>T | RNA (SNP) | VAF 30/87 reads (34%) | catalogued as rs754507115; called by muse, mutect2, varscan2
- CACNA1G | c.4422+208G>A | Intron (SNP) | VAF 28/69 reads (41%) | catalogued as rs199892912; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415202 C>G | 5'Flank (SNP) | VAF 24/65 reads (37%) | catalogued as rs1262332049, COSV52566539, COSV52566935; called by muse, mutect2, varscan2
- DST | c.4297-4635G>A | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as COSV55014582; called by muse, mutect2, varscan2
- GNB1 | c.*1C>T | 3'UTR (SNP) | VAF 20/68 reads (29%) | catalogued as rs761389908, COSV101060719; called by muse, mutect2, varscan2
- SLC22A20P | n.2436G>C | RNA (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- TTBK1 | c.1986+6312C>T | Intron (SNP) | VAF 61/174 reads (35%) | catalogued as rs765980032, COSV52490445; called by muse, mutect2, varscan2
